CCDI case PBBLRV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/c826528d-70d7-422b-9245-d111bc1a87b2

Demographics
Sex at birth: female; Race: asian; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Synovial sarcoma, spindle cell: ICD-O-3 morphology code: 9041/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 6.2 years (2,247 days).

Biospecimens (3 samples)
- Sample 0DC29K: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DC29Q: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DC2A0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
